Somatic mutation profile of tumor specimen MMRF_2365_1_BM_CD138pos (aliquot MMRF_2365_1_BM_CD138pos_T1_KHS5U_L11035) from MMRF case MMRF_2365, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 77.6 years (28,352 days).
Specimen MMRF_2365_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faed8fbb-e8c9-48a5-bf81-751fb9491eb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2365_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2365_1_PB_WBC_C2_KHS5U_L11036; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/798fb05e-2b96-4fdb-b90d-2d8b558d3ba9

The open-access MAF lists 51 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, 3'UTR 12, Intron 9, Silent 4, 3'Flank 3, 5'UTR 2, RNA 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 32/106 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C5orf15 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV51548933; called by muse, mutect2, varscan2
- FOXL3 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72563063; called by muse, mutect2, varscan2
- GSN | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs895304313; called by muse, mutect2, varscan2
- KCTD3 | c.1390C>G p.P464A | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV52065021; called by muse, varscan2
- TSKS | c.160T>C p.S54P | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55872728; called by muse, mutect2, varscan2
- UBE3C | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); catalogued as COSV61952692; called by muse, mutect2, varscan2
- VSX2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1042589251; called by muse, mutect2, varscan2
- ADAM19 | c.2546_2550+10del p.X849_splice | Splice Site (DEL) | VAF 17/94 reads (18%) | called by pindel, varscan2
- C11orf80 | c.1642A>T p.S548C | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- EXOC5 | c.743A>C p.E248A | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- GPR63 | c.219T>A p.F73L | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HELQ | c.965A>C p.K322T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- MKI67 | c.9337del p.E3113Kfs*3 | Frame Shift Del (DEL) | VAF 40/113 reads (35%) | called by mutect2, varscan2
- OR8H2 | c.25A>T p.N9Y | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHAC2 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- RPTOR | c.2332A>G p.I778V | Missense Mutation (SNP) | VAF 81/248 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, varscan2
- SLC22A12 | c.1124G>C p.G375A | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF853 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- ATP2B2 | c.3060C>A p.I1020= (on ENST00000352432; = p.I986= on NM_001683.5) | Silent (SNP) | VAF 55/247 reads (22%) | catalogued as rs1211104214; called by muse, mutect2, varscan2
- CCND1 | c.72C>T p.N24= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs1301043705; called by muse, mutect2, varscan2
- KAT6A | c.3786G>A p.E1262= | Silent (SNP) | VAF 117/319 reads (37%) | called by muse, mutect2, varscan2
- ZNF696 | c.1116C>T p.G372= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs1436956246; called by muse, mutect2, varscan2
- AC090517.4 | c.*172C>A | 3'UTR (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- ADCY1 | c.*6022G>A | 3'UTR (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- APH1B | c.*746dup | 3'UTR (INS) | VAF 21/52 reads (40%) | called by mutect2, varscan2
- DACH1 | chr13:71438228 T>G | 3'Flank (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- DBN1 | c.956-388C>G | Intron (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- FABP7 | c.348+1162C>A | Intron (SNP) | VAF 42/132 reads (32%) | called by muse, mutect2
- FPGT-TNNI3K | c.2114+3733C>A | Intron (SNP) | VAF 26/101 reads (26%) | called by muse, mutect2, varscan2
- GRIK4 | c.-159+3105C>T | Intron (SNP) | VAF 40/114 reads (35%) | catalogued as rs940667902; called by muse, mutect2, varscan2
- IGHV3-23 | c.-42T>A | 5'UTR (SNP) | VAF 20/70 reads (29%) | catalogued as rs781910615; called by muse, mutect2, varscan2
- MICB | c.*655G>T | 3'UTR (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2
- MIR4444-2 | n.45C>T | RNA (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- MYSM1 | c.*1070G>C | 3'UTR (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- NEB | c.18454-97C>G | Intron (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- NRK | c.*1659T>A | 3'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- PIEZO2 | chr18:10671380 del CAGAAGGATAT | 3'Flank (DEL) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- PPFIA2 | c.303+78474T>C | Intron (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- PPIA | c.*1521T>A | 3'UTR (SNP) | VAF 42/98 reads (43%) | called by muse, mutect2, varscan2
- PPP2R5C | c.405+135G>C | Intron (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- PRMT1 | c.643+40G>A | Intron (SNP) | VAF 72/192 reads (38%) | called by muse, mutect2, varscan2
- RNF152 | c.*1947A>C | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143623199 T>G | 3'Flank (SNP) | VAF 20/30 reads (67%) | called by muse, mutect2, varscan2
- SNX3 | c.-68G>A | 5'UTR (SNP) | VAF 4/70 reads (6%) | catalogued as COSV57778029; called by muse, mutect2
- SPN | c.*2995_*3004del | 3'UTR (DEL) | VAF 8/20 reads (40%) | catalogued as rs1567322014; called by mutect2, varscan2
- TMTC1 | c.*5994A>C | 3'UTR (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- TTC21A | c.2883+173G>A | Intron (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100086943; called by mutect2, varscan2
- USP28 | c.*874C>A | 3'UTR (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- ZNF697 | c.*1080C>A | 3'UTR (SNP) | VAF 26/64 reads (41%) | called by muse, mutect2, varscan2
